Somatic mutation profile of tumor specimen 0DK1WB from CCDI case PBBXTK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 12.2 years (4,474 days).
Specimen 0DK1WB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e950cf2-30b9-4c0a-95f1-bdc649135bd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK1WK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ac3d731-ce3d-4f76-829e-c33f7e7b8ffe

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Del 3, Silent 3, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCGR3B | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 450/2618 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372772013; called by muse, mutect2, varscan2
- KMT2D | c.902del p.F301Sfs*3 | Frame Shift Del (DEL) | VAF 278/785 reads (35%) | catalogued as COSV56466138; called by mutect2, pindel, varscan2
- PHF5A | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 311/679 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53439668, COSV53440444; called by muse, mutect2, varscan2
- TTN | c.17959G>C p.V5987L (on ENST00000591111; = p.V5060L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/755 reads (22%) | PolyPhen benign (0.341); catalogued as COSV60222523; called by muse, mutect2, varscan2
- ANPEP | c.2158-7T>A | Splice Region (SNP) | VAF 110/223 reads (49%) | called by muse, mutect2, varscan2
- C15orf65 | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 195/496 reads (39%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COL5A3 | c.3155G>A p.G1052D | Missense Mutation (SNP) | VAF 253/538 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GADL1 | c.722del p.T241Kfs*7 | Frame Shift Del (DEL) | VAF 164/498 reads (33%) | called by pindel, varscan2
- OTOF | c.2440del p.A814Pfs*3 (on ENST00000272371 / NM_194248.3; = p.A67Pfs*3 on NM_004802.4) | Frame Shift Del (DEL) | VAF 300/732 reads (41%) | called by mutect2, pindel, varscan2
- SMAD2 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 258/504 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TLN1 | c.5874dup p.E1959* | Frame Shift Ins (INS) | VAF 387/982 reads (39%) | called by mutect2, pindel, varscan2
- TTC21A | c.2975dup p.L992Ffs*5 | Frame Shift Ins (INS) | VAF 164/417 reads (39%) | called by mutect2, pindel, varscan2
- KCNH2 | c.1638C>T p.G546= | Silent (SNP) | VAF 282/1497 reads (19%) | catalogued as rs759245832, COSV100059193; called by muse, mutect2, varscan2
- MOGAT3 | c.240A>T p.I80= | Silent (SNP) | VAF 469/819 reads (57%) | called by muse, mutect2, varscan2
- SEMA5A | c.3153C>T p.F1051= | Silent (SNP) | VAF 256/590 reads (43%) | called by muse, mutect2, varscan2
- CFL2 | chr14:34714614 G>A | 5'Flank (SNP) | VAF 127/275 reads (46%) | catalogued as rs1170072662; called by muse, mutect2, varscan2
- HCAR2 | c.-19G>A | 5'UTR (SNP) | VAF 134/421 reads (32%) | catalogued as rs1474123120; called by muse, mutect2, varscan2
- MSI2 | c.312+41A>G | Intron (SNP) | VAF 246/745 reads (33%) | catalogued as rs779087184; called by muse, mutect2, varscan2
